Surgical pathology report (de-identified scan), TCGA case TCGA-80-5611, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR)/Ottawa, specimen TCGA-80-5611-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]						
A description for each data field can be found in the 'Data description' worksheet (yellow tab).						
[REDACTED]tion Details				Histology and staging		
TUMOUR	FF	LUL lung mass	Adenocarcinoma	[REDACTED]	011	RESECT

[page 2 of 3]
LUL	3.20	03	III	T2,NOS	N0	M0
-----	------	----	-----	--------	----	----

Source: NCI Genomic Data Commons file 2dfa0ea0-b18a-4abf-adb7-ffe807b7f059 (TCGA-80-5611.42E15634-A742-4E7C-A795-E5FE6FD7B9AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).